Somatic mutation profile of tumor specimen ALCH-ADI3-TTP1-A (aliquot ALCH-ADI3-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADI3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.8 years (17,441 days).
Specimen ALCH-ADI3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 179ffa85-ae18-4219-81dc-2238e6a3668e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADI3-NB1-A (Blood Derived Normal), aliquot ALCH-ADI3-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f2b736c-79d8-4dfd-b8d6-db7320d1a8e7

The open-access MAF lists 226 somatic variants for this specimen: 151 protein-altering or splice-affecting, 47 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 47, Intron 12, 3'UTR 9, Nonsense Mutation 5, Splice Site 4, RNA 3, Frame Shift Del 3, Splice Region 2, 5'Flank 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 1224/1942 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 150/578 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs876660254, COSV52672087, COSV52843475, COSV52949919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.5999C>G p.S2000* | Nonsense Mutation (SNP) | VAF 366/640 reads (57%) | catalogued as COSV70040948; called by muse, varscan2
- ABCA13 | c.6639C>G p.I2213M | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV101330137; called by muse, varscan2
- ABCA13 | c.7012C>T p.H2338Y | Missense Mutation (SNP) | VAF 182/350 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs746532329, COSV71292535; called by muse, mutect2, varscan2
- ABCA13 | c.7553C>T p.S2518L | Missense Mutation (SNP) | VAF 708/1208 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV101447138; called by muse, varscan2
- ABCA13 | c.7829C>T p.S2610L | Missense Mutation (SNP) | VAF 500/1009 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV71289309; called by muse, varscan2
- ACO1 | c.2633del p.G878Afs*6 | Frame Shift Del (DEL) | VAF 52/273 reads (19%) | catalogued as rs1563951892, COSV59379504; called by mutect2, pindel, varscan2
- AFF2 | c.3034G>T p.A1012S | Missense Mutation (SNP) | VAF 124/704 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.242); catalogued as rs782756910, COSV53987870; called by muse, mutect2, varscan2
- APOBEC3H | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.097); catalogued as COSV62379059; called by muse, mutect2, varscan2
- ATP1B4 | c.884A>G p.Y295C (on ENST00000218008 / NM_001142447.3; = p.Y291C on NM_012069.5) | Missense Mutation (SNP) | VAF 57/533 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569356658; called by muse, mutect2, varscan2
- BRS3 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); catalogued as rs1229759114; called by muse, mutect2, varscan2
- CD7 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs781565740, COSV53938342; called by muse, mutect2, varscan2
- CFAP47 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 152/757 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs924461410, COSV52882650; called by muse, mutect2, varscan2
- COL9A1 | c.1611+1G>C p.X537_splice | Splice Site (SNP) | VAF 113/639 reads (18%) | catalogued as COSV100294118; called by muse, mutect2, varscan2
- DOCK2 | c.3767A>G p.E1256G | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99910125; called by muse, mutect2, varscan2
- EGFR | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 652/1033 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs483352806, CM132767, COSV51780730; ClinVar: not provided / drug response; called by muse, mutect2, varscan2
- ELOVL4 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 91/387 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1356670683; called by muse, mutect2, varscan2
- ERCC6 | c.3460T>C p.S1154P | Missense Mutation (SNP) | VAF 92/493 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs111317675; called by muse, mutect2, varscan2
- FAM163B | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs374236190; called by muse, mutect2, varscan2
- FGGY | c.940G>T p.G314W | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58045658; called by muse, mutect2
- FNDC1 | c.2420C>T p.T807M | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs1436721059; called by muse, mutect2, varscan2
- GABRA4 | c.1247T>A p.V416D | Missense Mutation (SNP) | VAF 49/392 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV99974314; called by muse, mutect2, varscan2
- GRIK4 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV70800239; called by muse, mutect2, varscan2
- GRIN2C | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs539229067, COSV99500980; called by muse, mutect2, varscan2
- GRIN3A | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62458441; called by muse, varscan2
- HAUS5 | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV52548332; called by muse, mutect2, varscan2
- HRNR | c.2735G>C p.G912A | Missense Mutation (SNP) | VAF 117/938 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.905); catalogued as rs146160152, COSV64262201; called by muse, mutect2, varscan2
- IGHV7-81 | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1443486865; called by muse, varscan2
- LAMC3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 182/812 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs372107086, COSV100735914; called by muse, mutect2, varscan2
- LRIT1 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 108/534 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV100928200; called by muse, mutect2, varscan2
- LRRC37A | c.3409C>A p.L1137M | Missense Mutation (SNP) | VAF 112/881 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs755644745; called by muse, varscan2
- LRRC6 | c.727A>T p.S243C | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs1296691446; called by muse, mutect2, varscan2
- LRRTM3 | c.1687G>T p.D563Y | Missense Mutation (SNP) | VAF 92/488 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs751117205, COSV63668450; called by muse, mutect2, varscan2
- LYST | c.10143+1G>T p.X3381_splice | Splice Site (SNP) | VAF 84/557 reads (15%) | catalogued as COSV67707243; called by muse, mutect2, varscan2
- MAGEB6 | c.1168C>A p.L390M | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.111); catalogued as COSV66872736; called by muse, mutect2, varscan2
- MCTP2 | c.172G>C p.A58P | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as rs373786470; called by muse, mutect2, varscan2
- MLF1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 53/407 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.149); catalogued as COSV63035285; called by muse, mutect2, varscan2
- NADSYN1 | c.1351G>T p.V451L | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV99073942; called by muse, mutect2, varscan2
- NPY4R | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs149694580; called by mutect2, varscan2
- NRK | c.4606C>A p.R1536S | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as COSV104388015; called by muse, mutect2, varscan2
- NUTM1 | c.2705A>G p.N902S | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750832683; called by muse, mutect2, varscan2
- OR11H12 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 103/689 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1376149513, COSV73543692; called by muse, mutect2, varscan2
- OR2T35 | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 33/354 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV100442322; called by muse, mutect2, varscan2
- OR5L2 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV101004410; called by muse, mutect2, varscan2
- PAXIP1 | c.2897G>A p.R966Q | Missense Mutation (SNP) | VAF 55/424 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1242544250, COSV66898774; called by muse, mutect2, varscan2
- PRLR | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 91/606 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV51494405; called by muse, mutect2, varscan2
- RBM34 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 67/406 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs764523518, COSV100783870; called by muse, mutect2, varscan2
- RIT2 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 116/482 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58668027; called by muse, mutect2, varscan2
- SMYD1 | c.581del p.G194Afs*2 | Frame Shift Del (DEL) | VAF 21/184 reads (11%) | catalogued as COSV70225110; called by mutect2, pindel, varscan2
- TERT | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 141/1592 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as rs144697790, COSV57248812; ClinVar: uncertain significance; called by muse, mutect2
- THSD7B | c.3110C>G p.P1037R | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967125415, COSV55723546; called by mutect2, varscan2
- TSPAN6 | c.558G>C p.Q186H | Missense Mutation (SNP) | VAF 80/772 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV100885835, COSV65957581; called by muse, mutect2
- TYW1B | c.1591G>T p.G531W | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782620149; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3416C>G p.S1139C | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs909536421; called by muse, mutect2, varscan2
- ULBP2 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 92/725 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV66266116; called by muse, mutect2, varscan2
- ABCA13 | c.6225C>G p.I2075M | Missense Mutation (SNP) | VAF 820/1448 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, varscan2
- ABCA13 | c.7662C>G p.F2554L | Missense Mutation (SNP) | VAF 885/1476 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- ABCA13 | c.7868C>T p.S2623L | Missense Mutation (SNP) | VAF 562/1149 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, varscan2
- ACP7 | c.696G>T p.W232C | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRF4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 66/300 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1A1 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ALK | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 109/508 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD30B | c.1226-1G>T p.X409_splice | Splice Site (SNP) | VAF 29/126 reads (23%) | called by muse, varscan2
- ARHGEF28 | c.3860C>T p.A1287V | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- BPIFB6 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- BPIFB6 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- BSND | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, varscan2
- C1QC | c.501C>A p.Y167* | Nonsense Mutation (SNP) | VAF 71/675 reads (11%) | called by muse, mutect2, varscan2
- CACNA1B | c.4535C>A p.S1512Y | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CACNA2D2 | c.754A>T p.S252C | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC136 | c.1661A>T p.Q554L | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CCDC22 | c.1430T>A p.L477Q | Missense Mutation (SNP) | VAF 73/342 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC14C | c.1112C>A p.A371D (on ENST00000428251; = p.A264D on NM_152627.3) | Missense Mutation (SNP) | VAF 186/1440 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC27 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CELSR3 | c.1969C>G p.Q657E | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- CNBD1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CNKSR2 | c.1427A>T p.K476M | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CTAGE15 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 189/1840 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNND1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EYS | c.5318A>T p.N1773I | Missense Mutation (SNP) | VAF 76/470 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FGGY | c.939G>T p.W313C | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRMPD3 | c.1560C>G p.H520Q | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GIMAP2 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 259/802 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPR22 | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 102/303 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GRIN3A | c.1618G>T p.G540C | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN1 | c.2177A>T p.Q726L | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- HDAC9 | c.1403A>T p.H468L | Missense Mutation (SNP) | VAF 172/501 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HTN1 | c.102+1G>T p.X34_splice | Splice Site (SNP) | VAF 58/338 reads (17%) | called by muse, mutect2, varscan2
- HTR4 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV2-5 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- IPO13 | c.2141A>T p.K714M | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ITGA8 | c.38A>T p.Q13L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, varscan2
- ITGAL | c.2553G>T p.E851D | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- LCK | c.1003A>T p.K335* | Nonsense Mutation (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- LINC02740 | n.217G>T | Splice Region (SNP) | VAF 159/431 reads (37%) | called by muse, mutect2, varscan2
- LRRC9 | c.3669C>G p.N1223K | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LRRN3 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MAGEL2 | c.1787T>G p.V596G | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MDN1 | c.8494C>T p.Q2832* | Nonsense Mutation (SNP) | VAF 89/447 reads (20%) | called by muse, mutect2, varscan2
- MED23 | c.9_10del p.Q4Tfs*27 | Frame Shift Del (DEL) | VAF 102/682 reads (15%) | called by mutect2, pindel, varscan2
- MMEL1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2
- MMP16 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- MRC1 | c.3455G>T p.R1152L | Missense Mutation (SNP) | VAF 150/838 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- NELL1 | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 82/573 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEXMIF | c.1556A>G p.D519G | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NIPBL | c.2666G>T p.R889I | Missense Mutation (SNP) | VAF 77/479 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- NOTCH3 | c.2119G>T p.G707C | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRK | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR56A4 | c.529C>A p.R177S | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- P2RY10 | c.348C>A p.N116K | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PALB2 | c.1032C>A p.N344K | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDHA7 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 66/547 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- PDE6D | c.173C>G p.A58G | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PKP1 | c.1612A>T p.K538* | Nonsense Mutation (SNP) | VAF 45/276 reads (16%) | called by muse, mutect2, varscan2
- PPP1R3G | c.442T>A p.F148I | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PRKCH | c.1385A>G p.E462G | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PRRT3 | c.2131T>G p.C711G | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- PTPRF | c.3922G>T p.A1308S | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RALGPS2 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFPL4AL1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 276/2539 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- RHOBTB2 | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL3 | c.2536C>A p.Q846K | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- SEC31B | c.1524G>C p.E508D | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SERPINE2 | c.1158A>C p.T386= | Splice Region (SNP) | VAF 60/252 reads (24%) | called by muse, mutect2, varscan2
- SETBP1 | c.1981A>C p.K661Q | Missense Mutation (SNP) | VAF 239/1070 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SHANK1 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC26A8 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- SLC38A11 | c.1031T>A p.V344D (on ENST00000409149 / NM_001351539.1; = p.V322D on NM_173512.2) | Missense Mutation (SNP) | VAF 115/557 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- SLCO1B1 | c.1842G>T p.R614S | Missense Mutation (SNP) | VAF 76/391 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLPI | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SNAP91 | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SNX32 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SPAG17 | c.907C>A p.L303M | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPEG | c.4480G>C p.V1494L | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- STRIP1 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 115/526 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SUPT6H | c.1664A>G p.Q555R | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TBX21 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM4 | c.6861G>T p.W2287C | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TGM7 | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 119/524 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- TLE3 | c.2176G>T p.A726S | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- TRAV8-7 | c.16A>T p.I6F | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TTC27 | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC39C | c.668A>T p.Y223F (on ENST00000317571 / NM_001135993.2; = p.Y162F on NM_153211.4) | Missense Mutation (SNP) | VAF 110/417 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- TTN | c.22871A>G p.N7624S (on ENST00000591111; = p.N6697S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/335 reads (21%) | PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TYW1 | c.1783G>T p.G595W | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- VPS13C | c.1168A>T p.T390S (on ENST00000644861 / NM_020821.3; = p.T347S on NM_017684.5) | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZBTB1 | c.1136G>C p.S379T | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by mutect2, varscan2
- ZCCHC12 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 208/599 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ZNF536 | c.2519G>T p.G840V | Missense Mutation (SNP) | VAF 111/269 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ZNF727 | c.448T>C p.C150R | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ABCA13 | c.5865C>T p.I1955= | Silent (SNP) | VAF 1004/1788 reads (56%) | catalogued as rs746356057, COSV101330191; called by muse, mutect2, varscan2
- ABCA13 | c.7110C>T p.L2370= | Silent (SNP) | VAF 656/1202 reads (55%) | catalogued as COSV71286760; called by muse, varscan2
- ABCG8 | c.586C>A p.R196= | Silent (SNP) | VAF 130/622 reads (21%) | called by muse, mutect2, varscan2
- ANGPTL6 | c.207C>A p.V69= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- ANKRD27 | c.459C>T p.D153= | Silent (SNP) | VAF 114/398 reads (29%) | catalogued as COSV60129699; called by muse, mutect2, varscan2
- ATP11C | c.2109A>G p.L703= | Silent (SNP) | VAF 228/656 reads (35%) | called by muse, varscan2
- C1QTNF12 | c.192A>T p.S64= | Silent (SNP) | VAF 38/233 reads (16%) | called by muse, mutect2, varscan2
- C5orf52 | c.192G>T p.A64= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV101337555; called by muse, mutect2
- CACNA1B | c.4536C>G p.S1512= | Silent (SNP) | VAF 39/237 reads (16%) | catalogued as COSV99498712; called by muse, mutect2, varscan2
- CAPG | c.1014C>T p.P338= | Silent (SNP) | VAF 81/328 reads (25%) | called by muse, mutect2, varscan2
- COL19A1 | c.3258T>C p.P1086= | Silent (SNP) | VAF 24/187 reads (13%) | called by muse, mutect2, varscan2
- DCDC1 | c.4809T>A p.P1603= (on ENST00000597505 / NM_001367979.1; = p.P710= on NM_020869.3) | Silent (SNP) | VAF 101/304 reads (33%) | called by muse, mutect2, varscan2
- DLG1 | c.243T>C p.T81= | Silent (SNP) | VAF 54/303 reads (18%) | catalogued as rs1342556359; called by muse, mutect2, varscan2
- DYSF | c.699G>T p.P233= | Silent (SNP) | VAF 75/382 reads (20%) | called by muse, mutect2, varscan2
- ELFN1 | c.204C>T p.N68= | Silent (SNP) | VAF 43/288 reads (15%) | catalogued as rs777457873; called by muse, mutect2, varscan2
- FAM83C | c.432C>A p.T144= | Silent (SNP) | VAF 66/292 reads (23%) | catalogued as rs1250261661, COSV100981735; called by muse, mutect2, varscan2
- FLG | c.4704C>A p.A1568= | Silent (SNP) | VAF 102/643 reads (16%) | catalogued as rs766533034, COSV100910376, COSV64238428; called by muse, mutect2, varscan2
- GDF10 | c.594C>T p.R198= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs1555207489; called by muse, mutect2, varscan2
- HDGFL1 | c.219C>A p.R73= | Silent (SNP) | VAF 115/715 reads (16%) | called by muse, mutect2, varscan2
- HOXB9 | c.330G>T p.G110= | Silent (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- HSD3B1 | c.90G>A p.K30= | Silent (SNP) | VAF 72/496 reads (15%) | called by muse, mutect2, varscan2
- IL7R | c.543G>T p.V181= | Silent (SNP) | VAF 98/617 reads (16%) | catalogued as COSV57414603; called by muse, mutect2, varscan2
- INO80D | c.720A>T p.L240= | Silent (SNP) | VAF 64/286 reads (22%) | called by muse, mutect2, varscan2
- KCNQ5 | c.1770A>C p.I590= | Silent (SNP) | VAF 49/275 reads (18%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4995C>A p.T1665= (on ENST00000321505; = p.T1962= on NM_012194.3) | Silent (SNP) | VAF 87/531 reads (16%) | called by muse, mutect2, varscan2
- MEI1 | c.1617C>G p.T539= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as COSV100299745; called by muse, mutect2, varscan2
- MYH1 | c.1884G>A p.T628= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs769654863; called by muse, mutect2, varscan2
- MYH7 | c.4911C>A p.A1637= | Silent (SNP) | VAF 86/615 reads (14%) | called by muse, mutect2, varscan2
- NAV2 | c.6180G>T p.R2060= (on ENST00000396087 / NM_001244963.2; = p.R2001= on NM_145117.5) | Silent (SNP) | VAF 100/285 reads (35%) | called by muse, mutect2, varscan2
- NRROS | c.729G>A p.A243= | Silent (SNP) | VAF 56/283 reads (20%) | catalogued as COSV100145569; called by muse, mutect2, varscan2
- ODF2L | c.540A>G p.Q180= | Silent (SNP) | VAF 86/571 reads (15%) | catalogued as rs371613769; called by muse, mutect2, varscan2
- OR4A5 | c.690G>A p.R230= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as rs1443925966, COSV60524635; called by muse, mutect2, varscan2
- OR4P4 | c.201C>G p.S67= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as COSV100111568, COSV100111809; called by muse, mutect2, varscan2
- PDE1C | c.1047C>A p.I349= | Silent (SNP) | VAF 54/380 reads (14%) | called by muse, mutect2, varscan2
- PRDM14 | c.1326G>A p.E442= | Silent (SNP) | VAF 59/394 reads (15%) | called by muse, mutect2, varscan2
- RTL1 | c.3057A>T p.S1019= | Silent (SNP) | VAF 53/280 reads (19%) | called by muse, mutect2, varscan2
- SCN7A | c.4161C>T p.I1387= | Silent (SNP) | VAF 40/221 reads (18%) | called by muse, mutect2, varscan2
- SHOX | c.60C>T p.N20= | Silent (SNP) | VAF 83/482 reads (17%) | catalogued as COSV61860685, COSV61860861; called by muse, mutect2, varscan2
- SLC36A4 | c.372A>G p.S124= | Silent (SNP) | VAF 50/270 reads (19%) | called by muse, mutect2, varscan2
- SLC9A7 | c.1131C>G p.A377= | Silent (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- SPATC1 | c.507C>T p.S169= | Silent (SNP) | VAF 54/216 reads (25%) | called by muse, mutect2, varscan2
- SPRY3 | c.723C>A p.T241= | Silent (SNP) | VAF 95/731 reads (13%) | called by muse, mutect2, varscan2
- STAC | c.891A>T p.V297= | Silent (SNP) | VAF 57/311 reads (18%) | called by muse, mutect2, varscan2
- TLK1 | c.2271A>T p.T757= | Silent (SNP) | VAF 50/168 reads (30%) | called by muse, mutect2, varscan2
- TMPRSS12 | c.225G>C p.G75= | Silent (SNP) | VAF 55/334 reads (16%) | called by muse, mutect2, varscan2
- VSTM2B | c.726G>T p.P242= | Silent (SNP) | VAF 13/321 reads (4%) | catalogued as rs1459729748; called by muse, mutect2
- ZNF853 | c.1227G>T p.P409= | Silent (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- AC011773.3 | n.668-3712G>T | Intron (SNP) | VAF 52/281 reads (19%) | called by muse, mutect2, varscan2
- AKR1B1 | c.430-34C>A | Intron (SNP) | VAF 118/766 reads (15%) | called by muse, mutect2, varscan2
- ATAD3B | c.*235C>T | 3'UTR (SNP) | VAF 47/345 reads (14%) | catalogued as rs367740674; called by muse, mutect2, varscan2
- ATOH8 | c.960+8483G>A | Intron (SNP) | VAF 54/268 reads (20%) | called by muse, varscan2
- B3GNT4 | c.*910A>T | 3'UTR (SNP) | VAF 53/302 reads (18%) | catalogued as rs562052513; called by muse, mutect2, varscan2
- CAPN8 | c.899+16C>T | Intron (SNP) | VAF 39/215 reads (18%) | catalogued as rs924314366; called by mutect2, varscan2
- CCDC138 | c.267-34del | Intron (DEL) | VAF 82/402 reads (20%) | called by mutect2, pindel, varscan2
- CCDC74B | c.545-11C>A | Intron (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2
- CLEC1B | c.-7G>T | 5'UTR (SNP) | VAF 56/255 reads (22%) | called by muse, mutect2, varscan2
- CSF2RA | c.*173C>A | 3'UTR (SNP) | VAF 35/185 reads (19%) | called by muse, mutect2, varscan2
- GORAB | c.61+1321G>A | Intron (SNP) | VAF 72/291 reads (25%) | called by muse, mutect2, varscan2
- NBPF8 | n.2422C>A | RNA (SNP) | VAF 78/1654 reads (5%) | called by muse, mutect2
- NIPAL2 | c.*46C>T | 3'UTR (SNP) | VAF 61/509 reads (12%) | called by muse, mutect2, varscan2
- NRXN2 | c.1197+50dup | Intron (INS) | VAF 50/290 reads (17%) | catalogued as rs763412451; called by mutect2, varscan2
- NTRK3 | c.*35C>A | 3'UTR (SNP) | VAF 71/294 reads (24%) | catalogued as rs1415999432, COSV62298372; called by muse, mutect2, varscan2
- OR11H6 | chr14:20229621 G>C | 3'Flank (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- OR2P1P | chr6:29076438 G>A | 5'Flank (SNP) | VAF 44/310 reads (14%) | called by muse, mutect2, varscan2
- PSD3 | c.2086+29A>T | Intron (SNP) | VAF 77/334 reads (23%) | catalogued as COSV54080348; called by muse, mutect2, varscan2
- PTENP1 | n.1272C>T | RNA (SNP) | VAF 136/554 reads (25%) | catalogued as rs1438370044; called by muse, mutect2, varscan2
- RNF168 | c.*27T>A | 3'UTR (SNP) | VAF 59/282 reads (21%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*1370A>C | 3'UTR (SNP) | VAF 47/255 reads (18%) | called by muse, mutect2, varscan2
- SPATS1 | chr6:44342675 G>A | 5'Flank (SNP) | VAF 51/246 reads (21%) | called by muse, mutect2, varscan2
- SYT14 | c.*739T>C | 3'UTR (SNP) | VAF 65/445 reads (15%) | called by muse, mutect2, varscan2
- THAP4 | c.1241-10970G>T | Intron (SNP) | VAF 105/628 reads (17%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.269-42A>G | Intron (SNP) | VAF 32/143 reads (22%) | catalogued as rs1311395550; called by muse, mutect2, varscan2
- XIST | n.7879C>A | RNA (SNP) | VAF 73/211 reads (35%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1161C>T | Intron (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- ZNF875 | c.*17G>T | 3'UTR (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
